Somatic mutation profile of tumor specimen 0DDZK4 from CCDI case PBBNPJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 12.3 years (4,510 days).
Specimen 0DDZK4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22704126-e99b-4740-a28c-75e2f9407ef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDZK1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6de067b0-d95c-417d-b1ef-bf30a2411093

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Splice Region 3, Silent 3, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 927/985 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LOXHD1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 379/980 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.565); catalogued as rs184173766; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAN2C1 | c.101+3G>A | Splice Region (SNP) | VAF 16/194 reads (8%) | catalogued as rs1567291459; called by muse, mutect2
- MEF2C | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 218/777 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100425527; called by muse, mutect2, varscan2
- NF2 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 134/804 reads (17%) | catalogued as COSV58523413, COSV58530082, COSV58533698; called by muse, mutect2, varscan2
- PLEKHA6 | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 89/618 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55338312; called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 28/1102 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- FAM160A1 | c.721T>A p.Y241N | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2
- PGAM5 | c.192-3C>G | Splice Region (SNP) | VAF 453/1147 reads (39%) | called by muse, mutect2, varscan2
- RTL9 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 306/1046 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCL1B | c.*15+8G>A | Splice Region (SNP) | VAF 210/231 reads (91%) | called by muse, mutect2, varscan2
- TEPSIN | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 319/486 reads (66%) | SIFT tolerated (0.49); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ZNF676 | c.136G>T p.A46S (on ENST00000650058; = p.A14S on NM_001001411.3) | Missense Mutation (SNP) | VAF 277/692 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CA7 | c.495G>A p.A165= | Silent (SNP) | VAF 478/533 reads (90%) | catalogued as rs375080966; called by muse, mutect2, varscan2
- EDA2R | c.660C>T p.D220= | Silent (SNP) | VAF 368/774 reads (48%) | catalogued as rs749216567, COSV53633218; ClinVar: likely benign; called by muse, varscan2
- SLC25A53 | c.609G>T p.L203= | Silent (SNP) | VAF 321/1463 reads (22%) | called by muse, mutect2, varscan2
- C17orf107 | c.-119_-114del | 5'UTR (DEL) | VAF 200/278 reads (72%) | called by mutect2, varscan2
- PRRC2A | c.4936-57C>T | Intron (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
